Somatic mutation profile of cancer-model specimen HCM-BROD-0199-C71-85R (3D Neurosphere, passage 5; aliquot HCM-BROD-0199-C71-85R-01D-A80U-36), derived from the recurrence tumor of HCMI case HCM-BROD-0199-C71, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 49.1 years (17,924 days).
Specimen HCM-BROD-0199-C71-85R: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: 3D Neurosphere; Preservation method: Frozen; Passage count: 5.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f3936b1d-6aa4-4beb-bb03-611429f2f44c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0199-C71-10A (Blood Derived Normal), aliquot HCM-BROD-0199-C71-10A-01D-A786-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7958fabe-a863-4a46-b175-ed27387c3241

The open-access MAF lists 105 somatic variants for this specimen: 72 protein-altering or splice-affecting, 25 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 54, Silent 25, Frame Shift Del 10, Nonsense Mutation 4, 5'UTR 3, Intron 3, Splice Site 2, Frame Shift Ins 2, RNA 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CACNA1C | c.959C>T p.T320M | Missense Mutation (SNP) | VAF 171/367 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.703); catalogued as rs377737331; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CD163L1 | c.644G>A p.R215H | Missense Mutation (SNP) | VAF 228/461 reads (49%) | SIFT deleterious (0.03); PolyPhen benign (0.097); catalogued as rs139153315; called by muse, mutect2, varscan2
- CD209 | c.847G>A p.A283T | Missense Mutation (SNP) | VAF 196/428 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs139712001; called by muse, mutect2, varscan2
- CILP2 | c.3236G>A p.R1079H | Missense Mutation (SNP) | VAF 225/457 reads (49%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs1158706242; called by muse, mutect2, varscan2
- CTAGE6 | c.613C>T p.R205W | Missense Mutation (SNP) | VAF 32/122 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs1186223985; called by mutect2, varscan2
- DNAH6 | c.2237G>A p.S746N | Missense Mutation (SNP) | VAF 80/180 reads (44%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs781349744, COSV52856417; called by muse, mutect2, varscan2
- DNAI1 | c.373G>A p.D125N | Missense Mutation (SNP) | VAF 96/172 reads (56%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs752354598, COSV54280364, COSV54280621; called by muse, mutect2, varscan2
- DROSHA | c.892C>T p.R298* | Nonsense Mutation (SNP) | VAF 119/269 reads (44%) | catalogued as COSV60781622; called by muse, mutect2, varscan2
- ESPNL | c.28G>A p.A10T | Missense Mutation (SNP) | VAF 193/401 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as rs778024556, COSV54541083; called by muse, mutect2, varscan2
- GPSM2 | c.1123C>T p.L375F | Missense Mutation (SNP) | VAF 53/298 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.186); catalogued as COSV51442192; called by muse, mutect2, varscan2
- GRB7 | c.299G>A p.R100H | Missense Mutation (SNP) | VAF 169/353 reads (48%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.532); catalogued as rs201668668; called by muse, mutect2, varscan2
- GRIP1 | c.533G>A p.R178H | Missense Mutation (SNP) | VAF 204/394 reads (52%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs367635870; called by muse, mutect2, varscan2
- GUCY1B1 | c.1823dup p.N608Kfs*11 | Frame Shift Ins (INS) | VAF 78/193 reads (40%) | catalogued as rs757993339; called by mutect2, pindel, varscan2
- HMCN1 | c.10904G>A p.R3635Q | Missense Mutation (SNP) | VAF 188/369 reads (51%) | SIFT tolerated (0.31); PolyPhen benign (0.026); catalogued as rs777872545, COSV54908505; called by muse, mutect2, varscan2
- LETM1 | c.623G>A p.R208H | Missense Mutation (SNP) | VAF 152/244 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs201510306, COSV57103367; called by muse, mutect2, varscan2
- NLRP3 | c.1666G>A p.V556M | Missense Mutation (SNP) | VAF 135/300 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.161); catalogued as rs199637520; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NPIPB11 | c.1495C>A p.P499T | Missense Mutation (SNP) | VAF 162/172 reads (94%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.876); catalogued as rs796341971; called by mutect2, varscan2
- NRROS | c.727G>A p.A243T | Missense Mutation (SNP) | VAF 255/514 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0.06); catalogued as rs986757744; called by muse, mutect2, varscan2
- PCLO | c.8008C>A p.L2670I | Missense Mutation (SNP) | VAF 64/755 reads (8%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as COSV61623490; called by muse, mutect2
- PPP3R2 | c.374C>T p.T125M | Missense Mutation (SNP) | VAF 216/476 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.063); catalogued as rs1200972717, COSV62455332; called by muse, mutect2, varscan2
- PTEN | c.183T>G p.H61Q | Missense Mutation (SNP) | VAF 77/77 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64289119, COSV99057944; called by muse, mutect2, varscan2
- REPS2 | c.1883G>A p.R628Q | Missense Mutation (SNP) | VAF 161/161 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58184927; called by muse, mutect2, varscan2
- SLC12A4 | c.3245C>A p.T1082N | Missense Mutation (SNP) | VAF 14/364 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV50453053; called by muse, mutect2
- STIM2 | c.1006G>A p.E336K | Missense Mutation (SNP) | VAF 68/195 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV52838637; called by muse, mutect2, varscan2
- SVEP1 | c.6035del p.S2012Mfs*42 | Frame Shift Del (DEL) | VAF 172/438 reads (39%) | catalogued as COSV99928995; called by mutect2, pindel, varscan2
- TCTEX1D2 | c.332G>A p.C111Y | Missense Mutation (SNP) | VAF 113/227 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs148684369; called by muse, mutect2, varscan2
- TENT5D | c.500G>A p.R167Q | Missense Mutation (SNP) | VAF 169/169 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100382782; called by muse, mutect2, varscan2
- TSKS | c.1166G>A p.R389Q | Missense Mutation (SNP) | VAF 233/464 reads (50%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.859); catalogued as rs1317673712; called by muse, mutect2, varscan2
- TTC28 | c.2143C>T p.R715* | Nonsense Mutation (SNP) | VAF 175/342 reads (51%) | catalogued as COSV67414832; called by muse, mutect2, varscan2
- UBR4 | c.3617C>G p.S1206C | Missense Mutation (SNP) | VAF 173/376 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); catalogued as rs555728639, COSV64382807; called by muse, mutect2, varscan2
- ZNF333 | c.1295C>T p.T432M | Missense Mutation (SNP) | VAF 225/481 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1240772288; called by muse, mutect2, varscan2
- ZNF831 | c.1045C>T p.R349C | Missense Mutation (SNP) | VAF 282/554 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64040754; called by muse, mutect2, varscan2
- AHNAK2 | c.15899A>G p.H5300R | Missense Mutation (SNP) | VAF 57/336 reads (17%) | SIFT tolerated (0.53); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ANKRD18B | c.1484del p.L495* | Frame Shift Del (DEL) | VAF 180/365 reads (49%) | called by mutect2, pindel, varscan2
- ANKS1A | c.148G>A p.G50S | Missense Mutation (SNP) | VAF 327/507 reads (64%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); called by muse, mutect2, varscan2
- C1orf198 | c.446C>G p.A149G | Missense Mutation (SNP) | VAF 222/431 reads (52%) | SIFT tolerated (0.41); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CCT6A | c.998T>G p.L333R | Missense Mutation (SNP) | VAF 45/654 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.451); called by muse, mutect2
- CHD6 | c.4069G>T p.E1357* | Nonsense Mutation (SNP) | VAF 165/315 reads (52%) | called by muse, mutect2, varscan2
- CHD9 | c.957del p.E320Nfs*7 | Frame Shift Del (DEL) | VAF 117/296 reads (40%) | called by mutect2, pindel, varscan2
- CPA5 | c.412T>C p.S138P | Missense Mutation (SNP) | VAF 136/622 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.323); called by muse, mutect2, varscan2
- CPA6 | c.293T>G p.L98* | Nonsense Mutation (SNP) | VAF 128/274 reads (47%) | called by muse, mutect2, varscan2
- CRMP1 | c.1628del p.G543Vfs*4 | Frame Shift Del (DEL) | VAF 146/342 reads (43%) | called by mutect2, pindel, varscan2
- DAZL | c.400C>A p.P134T | Missense Mutation (SNP) | VAF 132/305 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- DDR2 | c.2132T>C p.L711P | Missense Mutation (SNP) | VAF 27/299 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- DGKI | c.956T>G p.V319G | Missense Mutation (SNP) | VAF 140/596 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- DPP4 | c.211A>G p.K71E | Missense Mutation (SNP) | VAF 80/146 reads (55%) | SIFT deleterious (0.05); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- EHMT2 | c.1792C>T p.P598S | Missense Mutation (SNP) | VAF 173/498 reads (35%) | SIFT tolerated (0.23); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- ESPL1 | c.3489G>T p.W1163C | Missense Mutation (SNP) | VAF 253/527 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- EXT1 | c.313G>C p.D105H | Missense Mutation (SNP) | VAF 97/260 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- FAM135A | c.1514del p.N505Tfs*5 | Frame Shift Del (DEL) | VAF 69/98 reads (70%) | called by mutect2, pindel, varscan2
- GRM6 | c.320A>C p.E107A | Missense Mutation (SNP) | VAF 371/700 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); called by muse, mutect2, varscan2
- GUCY1A1 | c.1561G>T p.D521Y | Missense Mutation (SNP) | VAF 16/276 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- JMJD8 | c.596del p.P199Hfs*122 | Frame Shift Del (DEL) | VAF 181/462 reads (39%) | called by mutect2, pindel, varscan2
- KCNN2 | c.529T>G p.S177A (on ENST00000264773; = p.S389A on NM_021614.4) | Missense Mutation (SNP) | VAF 13/362 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); called by muse, mutect2
- MYH6 | c.1411-2A>C p.X471_splice | Splice Site (SNP) | VAF 12/225 reads (5%) | called by muse, mutect2
- NEK5 | c.1199dup p.S401Kfs*6 | Frame Shift Ins (INS) | VAF 118/292 reads (40%) | called by mutect2, pindel, varscan2
- NOC4L | c.461T>C p.V154A | Missense Mutation (SNP) | VAF 153/333 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.471); called by muse, mutect2, varscan2
- NOX4 | c.1560del p.F520Lfs*2 | Frame Shift Del (DEL) | VAF 109/318 reads (34%) | called by mutect2, pindel, varscan2
- NRN1 | c.349del p.A117Rfs*20 | Frame Shift Del (DEL) | VAF 90/408 reads (22%) | called by mutect2, pindel, varscan2
- PAQR3 | c.349-1G>T p.X117_splice | Splice Site (SNP) | VAF 85/167 reads (51%) | called by muse, mutect2, varscan2
- PKP2 | c.1276G>T p.D426Y | Missense Mutation (SNP) | VAF 23/473 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); called by muse, mutect2
- RTBDN | c.543C>G p.C181W (on ENST00000393233 / NM_001270444.1; = p.C213W on NM_031429.2) | Missense Mutation (SNP) | VAF 287/577 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- SIPA1L1 | c.3463del p.S1155Hfs*23 | Frame Shift Del (DEL) | VAF 181/431 reads (42%) | called by mutect2, pindel, varscan2
- SLC6A13 | c.1583G>T p.W528L | Missense Mutation (SNP) | VAF 22/484 reads (5%) | SIFT tolerated (0.4); PolyPhen benign (0.012); called by muse, mutect2
- ST18 | c.1580C>A p.P527Q | Missense Mutation (SNP) | VAF 64/287 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.48); called by muse, mutect2, varscan2
- TG | c.1349C>A p.S450Y | Missense Mutation (SNP) | VAF 22/418 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); called by muse, mutect2
- TTC9 | c.40C>A p.P14T | Missense Mutation (SNP) | VAF 265/525 reads (50%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- UBE2Q1 | c.269A>G p.H90R | Missense Mutation (SNP) | VAF 277/602 reads (46%) | SIFT tolerated (0.42); PolyPhen benign (0); called by muse, mutect2, varscan2
- VPS13D | c.12159C>A p.F4053L | Missense Mutation (SNP) | VAF 108/211 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.525); called by muse, mutect2, varscan2
- ZAP70 | c.41G>T p.S14I | Missense Mutation (SNP) | VAF 247/492 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- ZNF462 | c.6174_6175del p.C2059Lfs*7 | Frame Shift Del (DEL) | VAF 113/322 reads (35%) | called by pindel, varscan2
- ZNF708 | c.1640T>G p.L547R | Missense Mutation (SNP) | VAF 64/130 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- AMOT | c.405A>G p.G135= | Silent (SNP) | VAF 295/295 reads (100%) | called by muse, mutect2, varscan2
- APIP | c.171C>T p.Y57= | Silent (SNP) | VAF 18/260 reads (7%) | called by muse, mutect2
- CCDC70 | c.18G>T p.V6= | Silent (SNP) | VAF 76/370 reads (21%) | called by muse, mutect2, varscan2
- CILP | c.1767G>A p.L589= | Silent (SNP) | VAF 269/522 reads (52%) | catalogued as COSV99973097; called by muse, mutect2, varscan2
- CLEC4M | c.627G>C p.T209= | Silent (SNP) | VAF 52/378 reads (14%) | catalogued as rs59003279; called by muse, varscan2
- DYSF | c.5046G>A p.Q1682= | Silent (SNP) | VAF 103/239 reads (43%) | called by muse, mutect2, varscan2
- FLNC | c.5433G>A p.R1811= | Silent (SNP) | VAF 174/849 reads (20%) | called by muse, mutect2, varscan2
- IGF1 | c.108G>A p.A36= | Silent (SNP) | VAF 174/432 reads (40%) | catalogued as rs371125874; called by muse, mutect2, varscan2
- LRBA | c.2019G>A p.K673= | Silent (SNP) | VAF 70/172 reads (41%) | called by muse, mutect2, varscan2
- MAP3K20 | c.1908G>A p.S636= | Silent (SNP) | VAF 155/281 reads (55%) | catalogued as rs112889653; called by mutect2, varscan2
- MUC12 | c.13509G>A p.P4503= (on ENST00000379442; = p.P4360= on NM_001164462.1) | Silent (SNP) | VAF 83/1792 reads (5%) | catalogued as rs775731625; called by muse, mutect2
- NCAM2 | c.1134T>C p.Y378= | Silent (SNP) | VAF 183/368 reads (50%) | called by muse, mutect2, varscan2
- OBSCN | c.21444G>A p.A7148= | Silent (SNP) | VAF 299/588 reads (51%) | catalogued as rs375088814; called by muse, mutect2
- PIK3C2G | c.2868C>T p.N956= (on ENST00000676171; = p.N915= on NM_004570.5) | Silent (SNP) | VAF 87/191 reads (46%) | called by muse, mutect2, varscan2
- RNF151 | c.360G>A p.S120= | Silent (SNP) | VAF 249/565 reads (44%) | catalogued as rs374940392, COSV58400005; called by muse, mutect2, varscan2
- RRP1 | c.807C>T p.P269= | Silent (SNP) | VAF 119/223 reads (53%) | catalogued as rs774930391, COSV101513845, COSV101513866; called by muse, mutect2, varscan2
- SCUBE2 | c.855G>A p.T285= | Silent (SNP) | VAF 91/208 reads (44%) | catalogued as rs553227629; called by muse, mutect2, varscan2
- SEMA3C | c.720G>T p.V240= | Silent (SNP) | VAF 113/636 reads (18%) | called by muse, mutect2, varscan2
- SOCS4 | c.225G>A p.E75= | Silent (SNP) | VAF 132/235 reads (56%) | called by muse, mutect2, varscan2
- SPOCD1 | c.867C>T p.P289= | Silent (SNP) | VAF 215/423 reads (51%) | catalogued as rs370591004, COSV57100233; called by muse, mutect2, varscan2
- SPTB | c.2082G>A p.E694= | Silent (SNP) | VAF 84/459 reads (18%) | called by muse, mutect2, varscan2
- TAF3 | c.2118G>A p.K706= | Silent (SNP) | VAF 146/146 reads (100%) | called by muse, varscan2
- TGM7 | c.732C>T p.G244= | Silent (SNP) | VAF 247/510 reads (48%) | catalogued as rs765744133; called by muse, mutect2, varscan2
- TM6SF2 | c.600C>T p.T200= | Silent (SNP) | VAF 111/224 reads (50%) | catalogued as rs748636134; called by muse, mutect2, varscan2
- ZSWIM4 | c.231G>A p.R77= | Silent (SNP) | VAF 192/390 reads (49%) | catalogued as rs1203070982, COSV99584488; called by muse, mutect2, varscan2
- C6orf89 | c.-129del | 5'UTR (DEL) | VAF 183/286 reads (64%) | called by mutect2, varscan2
- DYNLT1 | c.-24C>G | 5'UTR (SNP) | VAF 82/223 reads (37%) | catalogued as rs574899245; called by muse, mutect2, varscan2
- HGF | c.482+1183C>T | Intron (SNP) | VAF 26/663 reads (4%) | called by muse, mutect2
- ICOSLG | c.898+428G>A | Intron (SNP) | VAF 36/154 reads (23%) | catalogued as rs796098725; called by muse, varscan2
- OSTF1P1 | n.492C>T | RNA (SNP) | VAF 48/340 reads (14%) | catalogued as rs1474296193; called by muse, mutect2, varscan2
- SP110 | c.1815+349T>G | Intron (SNP) | VAF 129/265 reads (49%) | called by muse, mutect2, varscan2
- TMEM37 | c.-46G>A | 5'UTR (SNP) | VAF 175/399 reads (44%) | called by muse, mutect2, varscan2
- WDR45 | c.*102G>C | 3'UTR (SNP) | VAF 32/154 reads (21%) | catalogued as rs943051326, COSV59876297; called by muse, mutect2
